Somatic mutation profile of tumor specimen TARGET-10-PANWSP-09A (aliquot TARGET-10-PANWSP-09A-01D) from TARGET case TARGET-10-PANWSP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,197 days).
Specimen TARGET-10-PANWSP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db6a2e29-6c3d-4ea0-afb4-9fe682e7b4b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWSP-10A (Blood Derived Normal), aliquot TARGET-10-PANWSP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c8325c2-34e5-4de2-ac46-af9a528f5074

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.1586A>T p.D529V | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as CM074733; called by muse, mutect2, varscan2
- H4C5 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.615); catalogued as rs752651799; called by muse, mutect2, varscan2
- JADE3 | c.2066A>G p.D689G | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1556374070; called by muse, mutect2
- SLCO6A1 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as COSV65814138; called by muse, mutect2
- CCAR1 | c.1637C>A p.A546E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- USP15 | c.1816C>A p.L606I (on ENST00000280377 / NM_001351159.2; = p.L577I on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2
- ZNF488 | c.740A>G p.Q247R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF81 | c.*2509C>A | 3'UTR (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
